Somatic mutation profile of tumor specimen TCGA-FA-A7Q1-01A (aliquot TCGA-FA-A7Q1-01A-11D-A382-10) from TCGA case TCGA-FA-A7Q1, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Specified parts of peritoneum; Age at diagnosis: 61.5 years (22,454 days).
Specimen TCGA-FA-A7Q1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6232ec84-255b-4e89-a2c1-f0c920f54370.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FA-A7Q1-10A (Blood Derived Normal), aliquot TCGA-FA-A7Q1-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ad28a17-1557-403b-a858-b558dcc3ded4

The open-access MAF lists 193 somatic variants for this specimen: 132 protein-altering or splice-affecting, 52 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 52, Nonsense Mutation 10, Frame Shift Del 4, In Frame Del 4, Splice Site 4, 5'Flank 4, 3'Flank 2, 5'UTR 2, Frame Shift Ins 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 158/264 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 42/92 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1057519952, COSV69041759; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TRAF7 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as rs1331463984, COSV100399746; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.4966G>A p.V1656I | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs758912686, COSV100933067, COSV64677260; called by muse, varscan2
- ADGRB3 | c.2432C>A p.A811D | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV101001529; called by muse, mutect2, varscan2
- AKT2 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs745550650, COSV60908132; called by muse, mutect2, varscan2
- ALMS1 | c.3941C>A p.S1314* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV100043294; called by muse, mutect2, varscan2
- ANK3 | c.12145G>A p.V4049I | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs1478745817, COSV99781535; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3553A>G p.T1185A | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99784034; called by muse, mutect2, varscan2
- ARHGAP6 | c.2180T>G p.L727R (on ENST00000337414 / NM_013427.3; = p.L524R on NM_013423.3) | Missense Mutation (SNP) | VAF 144/469 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100273399, COSV57297433; called by muse, mutect2, varscan2
- ARHGEF2 | c.2929C>T p.R977C (on ENST00000361247 / NM_001162383.2; = p.R949C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs1404451460, COSV100560939; called by muse, mutect2, varscan2
- AVIL | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99142528; called by muse, mutect2, varscan2
- BCL7A | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV104379378, COSV55848650, COSV99947183; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4725G>T p.E1575D | Missense Mutation (SNP) | VAF 56/61 reads (92%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.078); catalogued as COSV100863879; called by muse, mutect2, varscan2
- CAD | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs757541618, COSV99255491; called by muse, mutect2, varscan2
- CALY | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1401102026, COSV99428680; called by muse, mutect2, varscan2
- CCDC81 | c.1818G>T p.R606= (on ENST00000445632 / NM_001156474.2; = p.R516= on NM_021827.4) | Splice Region (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99564672; called by muse, mutect2, varscan2
- CD163L1 | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100550517; called by muse, mutect2, varscan2
- CD70 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 76/95 reads (80%) | catalogued as rs777583938, COSV99835549; called by muse, mutect2, varscan2
- CDH11 | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV51750992, COSV99219375; called by muse, mutect2, varscan2
- CHRM3 | c.1117G>C p.G373R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as COSV99699195; called by muse, mutect2, varscan2
- CIITA | c.2372G>A p.R791K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100162445; called by muse, mutect2, varscan2
- CLCA2 | c.1271A>C p.K424T | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV100991650; called by muse, mutect2, varscan2
- COG4 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as rs1448610560, COSV55367699; called by muse, mutect2
- COL16A1 | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); catalogued as COSV99595129; called by muse, mutect2, varscan2
- COL21A1 | c.1717A>T p.R573* | Nonsense Mutation (SNP) | VAF 188/225 reads (84%) | catalogued as COSV99779650; called by muse, mutect2, varscan2
- COMP | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721543; called by muse, varscan2
- CREBBP | c.1921T>C p.Y641H | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99271157; called by muse, mutect2, varscan2
- CSNK1E | c.1170_1172del p.S391del | In Frame Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs1198230227; called by pindel, varscan2
- CTPS2 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 158/628 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100826980; called by muse, mutect2, varscan2
- CTRC | c.433_435del p.K145del | In Frame Del (DEL) | VAF 19/51 reads (37%) | catalogued as rs1299358808; called by mutect2, pindel, varscan2
- CYP4F3 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV99658532; called by muse, mutect2, varscan2
- DCAF6 | c.1709A>G p.D570G (on ENST00000312263 / NM_001349778.1; = p.D590G on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 250/412 reads (61%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1274532018, COSV100394641; called by muse, mutect2, varscan2
- DGKK | c.2828G>T p.G943V | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557224236, COSV101053150; called by muse, mutect2, varscan2
- DHRS2 | c.7T>A p.S3T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs765528019, COSV99159895; called by muse, mutect2, varscan2
- DIP2C | c.4073C>T p.A1358V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.315); catalogued as COSV99793165; called by muse, mutect2, varscan2
- DNAH9 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs377415601, COSV99307277; called by muse, mutect2, varscan2
- FAM135B | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 75/125 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs746882944, COSV52747605, COSV99426212; called by muse, mutect2, varscan2
- FAS | c.*2+1G>C | Splice Site (SNP) | VAF 64/95 reads (67%) | catalogued as CS121552, CS994526, COSV100570862, COSV58238227, COSV58238706; called by muse, mutect2, varscan2
- FBN2 | c.2638G>A p.G880S | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs555682061, COSV99329689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG2 | c.3964A>T p.T1322S | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV101166081; called by muse, mutect2, varscan2
- FLNA | c.7360A>T p.T2454S (on ENST00000369850 / NM_001110556.2; = p.T2446S on NM_001456.3) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV61047370; called by muse, mutect2, varscan2
- FLNC | c.6005-1G>A p.X2002_splice | Splice Site (SNP) | VAF 27/75 reads (36%) | catalogued as COSV100368530; called by muse, mutect2, varscan2
- FOXD4 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100071153; called by muse, varscan2
- FOXD4L1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.374); catalogued as rs755139743, COSV52075704; called by muse, mutect2, varscan2
- GABRG3 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1181064418, COSV61509011, COSV61531239; called by muse, mutect2, varscan2
- GP2 | c.1600G>C p.A534P (on ENST00000381362 / NM_001007240.3; = p.A531P on NM_001502.4) | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV100221594; called by muse, mutect2, varscan2
- GPAT2 | c.1835A>G p.Y612C | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV100853334; called by muse, mutect2, varscan2
- GPRIN2 | c.844T>A p.L282M | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); catalogued as COSV100966446; called by muse, mutect2, varscan2
- H3-3A | c.45A>C p.K15N | Missense Mutation (SNP) | VAF 135/211 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100831337; called by muse, mutect2, varscan2
- H3C2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV52517730, COSV52518686, COSV99451691; called by muse, mutect2, varscan2
- HECW1 | c.390C>A p.N130K | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101222791, COSV101224126; called by muse, mutect2, varscan2
- HMMR | c.269A>C p.E90A | Missense Mutation (SNP) | VAF 91/392 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100701037; called by muse, mutect2, varscan2
- HSF2BP | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1202095399, COSV99375666; called by muse, mutect2
- IGHV6-1 | c.94G>C p.V32L | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs782394872; called by muse, mutect2, varscan2
- IGKV3D-11 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as rs761599298; called by muse, mutect2, varscan2
- IGLC2 | c.252C>G p.S84R | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as rs775189745; called by muse, mutect2, varscan2
- IGLV3-1 | c.320A>C p.Q107P | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs192317432; called by muse, varscan2
- IGSF3 | c.2954G>A p.R985H (on ENST00000369486 / NM_001007237.3; = p.R1005H on NM_001542.4) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs374600687; called by muse, mutect2, varscan2
- IKZF3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 82/137 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53108135; called by muse, mutect2, varscan2
- IL4I1 | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV100352256; called by muse, mutect2, varscan2
- IRF1 | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 64/93 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99810650; called by muse, mutect2, varscan2
- KCNT1 | c.1988G>A p.R663Q (on ENST00000488444; = p.R682Q on NM_020822.3) | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs1188425438, COSV99706366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF13A | c.3326T>G p.L1109R | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99437444; called by muse, mutect2, varscan2
- KIF4B | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs193075545, COSV70530934; called by muse, mutect2, varscan2
- KLF2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.548); catalogued as COSV99934233; called by muse, varscan2
- KLF2 | c.1068G>C p.*356Yext*62 | Nonstop Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99934234; called by muse, mutect2, varscan2
- KLHL14 | c.99C>G p.C33W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100809183, COSV63835122; called by muse, mutect2, varscan2
- LRRC73 | c.33G>C p.E11D | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV99447264; called by muse, mutect2, varscan2
- MAP1S | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV100141142; called by muse, mutect2, varscan2
- MAP7D3 | c.2521A>G p.K841E | Missense Mutation (SNP) | VAF 180/607 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100286567; called by muse, mutect2, varscan2
- MED12 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379305; called by muse, mutect2, varscan2
- MFSD14B | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 125/337 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1289834617, COSV64700838; called by muse, mutect2, varscan2
- MICAL3 | c.2963G>A p.G988E | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101269817; called by muse, mutect2, varscan2
- MROH2B | c.2120C>A p.A707E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV101270854; called by muse, mutect2, varscan2
- MROH2B | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as COSV68181002; called by muse, mutect2, varscan2
- MSX1 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV101235739; called by muse, mutect2, varscan2
- MTMR1 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 167/279 reads (60%) | catalogued as COSV64892948; called by muse, varscan2
- MYH14 | c.3391C>T p.R1131W | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373919106, COSV51824636; called by muse, mutect2, varscan2
- MYO1E | c.1141G>T p.E381* | Nonsense Mutation (SNP) | VAF 66/164 reads (40%) | catalogued as COSV99896315; called by muse, mutect2, varscan2
- NAAA | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as COSV99716038; called by muse, mutect2, varscan2
- NACC2 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53198653; called by muse, mutect2, varscan2
- NFYC | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100438637; called by muse, mutect2, varscan2
- NKX6-3 | c.713A>G p.D238G (on ENST00000518699 / NM_001364841.2; = p.D108G on NM_152568.3) | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs766498627, COSV101570823; called by muse, mutect2, varscan2
- NXF1 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs781740092, COSV99586301; called by muse, mutect2, varscan2
- OR10H3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1479729939, COSV100008471; called by muse, varscan2
- OR2A7 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs747912287, COSV71827132; called by muse, mutect2, varscan2
- OR2L2 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 87/147 reads (59%) | catalogued as rs546778867, COSV63547603; called by muse, mutect2, varscan2
- ORC5 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV99857246; called by muse, mutect2, varscan2
- PCDHB13 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs782706910, COSV53401503; called by muse, mutect2
- PCF11 | c.251T>G p.V84G | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100018995; called by muse, mutect2, varscan2
- PEX5L | c.860G>A p.W287* | Nonsense Mutation (SNP) | VAF 93/234 reads (40%) | catalogued as rs866170332, COSV99829501; called by muse, mutect2, varscan2
- PGBD1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV99460711; called by muse, mutect2, varscan2
- PGD | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99581613; called by muse, mutect2, varscan2
- PLCE1 | c.6662C>T p.A2221V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV99596424; called by muse, mutect2, varscan2
- PRDM9 | c.2398G>T p.G800W | Missense Mutation (SNP) | VAF 88/150 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57012883, COSV99690930; called by muse, mutect2, varscan2
- RBM12 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.066); catalogued as COSV100467886, COSV58292143; called by muse, mutect2, varscan2
- RHOT1 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs747726637, COSV61714256; called by muse, mutect2, varscan2
- RIMS4 | c.591+1G>T p.X197_splice | Splice Site (SNP) | VAF 50/106 reads (47%) | catalogued as COSV100865196, COSV65719593; called by muse, mutect2, varscan2
- SALL1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 90/157 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs376234367, COSV51753527; called by muse, mutect2, varscan2
- SCGN | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 66/74 reads (89%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.784); catalogued as rs1251013324, COSV58545991, COSV58547188; called by muse, mutect2, varscan2
- SEMA3C | c.1285T>A p.Y429N | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99543572; called by muse, mutect2, varscan2
- SHROOM3 | c.1784A>T p.K595I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99934999; called by muse, mutect2, varscan2
- SOCS1 | c.364G>T p.G122* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100130547, COSV59661818; called by muse, mutect2, varscan2
- SPRY3 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100249475, COSV57143222; called by muse, mutect2, varscan2
- SPTBN4 | c.6434C>T p.A2145V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); catalogued as rs1166728004, COSV100151718; called by muse, mutect2, varscan2
- SYMPK | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99841961; called by muse, mutect2, varscan2
- TBC1D10B | c.896T>A p.L299Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV101329648; called by muse, mutect2, varscan2
- TBL1XR1 | c.1259T>C p.F420S | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101467784, COSV70504656; called by muse, mutect2, varscan2
- TECRL | c.774+1G>T p.X258_splice | Splice Site (SNP) | VAF 149/375 reads (40%) | catalogued as COSV101169246; called by muse, mutect2, varscan2
- TET2 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99484131; called by muse, mutect2, varscan2
- TMEM237 | c.215T>G p.L72R (on ENST00000409883 / NM_001044385.3; = p.L64R on NM_152388.4) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.16); catalogued as COSV99636115; called by muse, mutect2, varscan2
- TRPC5 | c.1612C>A p.L538I | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53303378, COSV99462193; called by muse, mutect2, varscan2
- UACA | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100537644; called by muse, mutect2, varscan2
- VPS51 | c.1093A>G p.N365D | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV99659758; called by muse, mutect2, varscan2
- ZAN | c.5242C>T p.P1748S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100770058; called by muse, mutect2, varscan2
- ZBP1 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100473753; called by muse, mutect2, varscan2
- ZBTB40 | c.2285A>C p.K762T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV100989078, COSV65145195; called by muse, mutect2, varscan2
- ZNF492 | c.1556A>G p.K519R | Missense Mutation (SNP) | VAF 198/551 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101514037; called by muse, mutect2, varscan2
- ZNF569 | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749391116, COSV100386579; called by muse, mutect2, varscan2
- BTG2 | c.82_90del p.G28_V30del | In Frame Del (DEL) | VAF 34/115 reads (30%) | called by mutect2, varscan2
- CHD9 | c.1823_1826del p.K608Mfs*18 | Frame Shift Del (DEL) | VAF 142/539 reads (26%) | called by pindel, varscan2
- CSK | c.1080_1081del p.K361Efs*5 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by pindel, varscan2
- DENND3 | c.3388_3389dup p.K1131Rfs*22 | Frame Shift Ins (INS) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- IGHG3 | c.365C>A p.T122K | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.99); PolyPhen benign (0.041); called by muse, varscan2
- IGLC3 | c.266T>G p.V89G | Missense Mutation (SNP) | VAF 37/120 reads (31%) | PolyPhen probably damaging (0.999); called by muse, varscan2
- IGLV4-3 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KLHL17 | c.1751del p.G584Vfs*100 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- MLLT6 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.413G>C p.C138S | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT tolerated (0.96); PolyPhen benign (0.084); called by muse, mutect2
- TAS2R14 | c.616_630del p.W206_K210del | In Frame Del (DEL) | VAF 76/140 reads (54%) | called by mutect2, varscan2
- TPP2 | c.3123_3126del p.Y1042Tfs*3 | Frame Shift Del (DEL) | VAF 48/57 reads (84%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.366C>T p.S122= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100619007; called by muse, mutect2, varscan2
- ADCY4 | c.201C>T p.C67= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV99353386; called by muse, mutect2, varscan2
- ARHGAP30 | c.267C>T p.C89= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs767483558, COSV100920158; called by muse, mutect2, varscan2
- BANP | c.609G>A p.T203= (on ENST00000286122; = p.T172= on NM_017869.4) | Silent (SNP) | VAF 46/76 reads (61%) | catalogued as rs372273341; called by muse, mutect2, varscan2
- C7 | c.1281G>A p.L427= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as COSV100496328, COSV57480113; called by muse, mutect2, varscan2
- CCDC47 | c.24T>C p.C8= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV99854282; called by muse, mutect2, varscan2
- CD14 | c.624C>T p.G208= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs1323013200, COSV100117601; called by muse, mutect2, varscan2
- CHID1 | c.324C>T p.P108= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs774048290, COSV100060060; called by muse, mutect2, varscan2
- COBL | c.930A>G p.P310= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV99473597; called by muse, mutect2, varscan2
- COL5A1 | c.5299C>T p.L1767= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100880334; called by muse, mutect2, varscan2
- CRKL | c.660C>T p.S220= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs763765173, COSV100574184; called by muse, mutect2, varscan2
- CSPG4 | c.3324C>T p.S1108= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs777826922, COSV100414000; called by muse, mutect2, varscan2
- FAT3 | c.3756C>G p.P1252= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV99968866; called by muse, mutect2, varscan2
- FBXW11 | c.834A>T p.G278= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as rs963358222, COSV99441216; called by muse, mutect2, varscan2
- FTMT | c.525G>A p.L175= | Silent (SNP) | VAF 38/64 reads (59%) | catalogued as COSV100360216; called by muse, mutect2, varscan2
- GOLGB1 | c.5316C>T p.N1772= | Silent (SNP) | VAF 134/343 reads (39%) | catalogued as COSV100511345; called by muse, mutect2, varscan2
- GPR158 | c.3045C>A p.T1015= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100894118; called by muse, mutect2, varscan2
- GRIPAP1 | c.1914C>T p.N638= | Silent (SNP) | VAF 116/185 reads (63%) | catalogued as COSV100904355; called by muse, mutect2, varscan2
- H2AC17 | c.171G>A p.E57= | Silent (SNP) | VAF 105/118 reads (89%) | catalogued as COSV100377683; called by muse, mutect2, varscan2
- HAUS8 | c.739C>T p.L247= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV99505438; called by muse, mutect2, varscan2
- HEATR5B | c.3978G>A p.A1326= | Silent (SNP) | VAF 110/256 reads (43%) | catalogued as rs775415181, COSV99249966; called by muse, varscan2
- HSPG2 | c.2037C>T p.R679= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs377560753; called by muse, mutect2, varscan2
- IARS1 | c.1890C>T p.S630= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV65117092; called by muse, mutect2, varscan2
- IGHG3 | c.222C>T p.S74= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs1240662886; called by muse, mutect2, varscan2
- IGHG3 | c.51C>T p.S17= | Silent (SNP) | VAF 15/38 reads (39%) | called by muse, varscan2
- IGLV3-1 | c.96C>A p.S32= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs370205939; called by muse, mutect2, varscan2
- IGLV3-10 | c.321C>T p.Y107= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1065471; called by muse, mutect2, varscan2
- KLHL4 | c.600C>A p.L200= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV100909487, COSV100910074; called by muse, mutect2, varscan2
- KRBA1 | c.948C>T p.T316= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99752982; called by muse, mutect2, varscan2
- KRT79 | c.1179G>A p.A393= | Silent (SNP) | VAF 63/95 reads (66%) | catalogued as rs573197551, COSV57939073; called by muse, mutect2, varscan2
- LRP2 | c.1704G>A p.S568= | Silent (SNP) | VAF 101/207 reads (49%) | catalogued as rs774520988, COSV99786970; called by muse, mutect2, varscan2
- NAV2 | c.3459C>T p.A1153= (on ENST00000396087 / NM_001244963.2; = p.A1130= on NM_145117.5) | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs777309149, COSV100217471; called by muse, mutect2, varscan2
- NEB | c.9054C>T p.D3018= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as rs756787775, COSV51459352; called by muse, mutect2, varscan2
- OR5M11 | c.405G>A p.T135= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs753561224, COSV73141683; called by muse, mutect2, varscan2
- POLE | c.2682C>T p.G894= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs757453683, COSV100267758; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PSEN1 | c.342C>T p.I114= | Silent (SNP) | VAF 71/191 reads (37%) | catalogued as COSV99998007; called by muse, mutect2, varscan2
- RC3H1 | c.2646C>T p.I882= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as COSV99281635, COSV99281735; called by muse, mutect2, varscan2
- RNF123 | c.2908C>T p.L970= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100246684; called by muse, mutect2, varscan2
- RTN4RL1 | c.1104G>A p.A368= | Silent (SNP) | VAF 64/210 reads (30%) | catalogued as rs773939053, COSV100486726; called by muse, mutect2, varscan2
- S1PR2 | c.459G>A p.G153= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as COSV100495346; called by muse, mutect2, varscan2
- SDCCAG8 | c.321T>C p.H107= | Silent (SNP) | VAF 115/435 reads (26%) | catalogued as COSV59420707; called by muse, mutect2, varscan2
- SERPINB9 | c.993A>G p.A331= | Silent (SNP) | VAF 69/87 reads (79%) | catalogued as COSV101046696; called by muse, mutect2, varscan2
- SGSH | c.1221C>T p.T407= | Silent (SNP) | VAF 79/136 reads (58%) | catalogued as COSV100413551; called by muse, mutect2, varscan2
- SOCS1 | c.240C>T p.Y80= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs758219786, COSV100130548, COSV59658883; called by muse, mutect2, varscan2
- TBX4 | c.1368C>T p.P456= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99540553; called by muse, mutect2, varscan2
- TECTA | c.915C>T p.C305= | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as rs367974065; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TLN2 | c.7206G>A p.A2402= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs74020685, COSV100169736; called by muse, mutect2, varscan2
- XRN1 | c.3027G>A p.V1009= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as rs1410567279, COSV99378685; called by muse, mutect2, varscan2
- ZBTB20 | c.624C>G p.G208= (on ENST00000474710 / NM_001164342.2; = p.G135= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100614739; called by muse, mutect2, varscan2
- ZC3H11A | c.2349C>A p.G783= | Silent (SNP) | VAF 99/335 reads (30%) | catalogued as COSV100142589; called by muse, mutect2, varscan2
- ZDHHC18 | c.906C>T p.L302= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs184688847, COSV100938863; called by muse, mutect2, varscan2
- ZNF703 | c.1515C>T p.S505= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as COSV100521769; called by muse, mutect2, varscan2
- FMN1 | c.2044-2552G>T | Intron (SNP) | VAF 63/151 reads (42%) | catalogued as COSV100569176; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901034 A>G | 3'Flank (SNP) | VAF 74/477 reads (16%) | catalogued as rs1360879026; called by muse, varscan2
- MIR9-1 | chr1:156416804 C>G | 3'Flank (SNP) | VAF 36/165 reads (22%) | catalogued as rs1325908891, COSV100024293; called by muse, mutect2, varscan2
- S1PR3 | c.-177C>T | 5'UTR (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100560948; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331247 C>A | 5'Flank (SNP) | VAF 42/68 reads (62%) | called by muse, varscan2
- TSPOAP1 | chr17:58331255 A>T | 5'Flank (SNP) | VAF 23/79 reads (29%) | called by muse, varscan2
- TSPOAP1 | chr17:58331260 A>G | 5'Flank (SNP) | VAF 26/82 reads (32%) | catalogued as rs756348475; called by muse, varscan2
- ZNF578 | chr19:52451239 C>T | 5'Flank (SNP) | VAF 6/16 reads (38%) | catalogued as COSV56520528; called by muse, varscan2
- ZNF688 | c.-617G>T | 5'UTR (SNP) | VAF 27/43 reads (63%) | catalogued as COSV99794318; called by muse, mutect2, varscan2
